Somatic mutation profile of tumor specimen 0DV5SE from CCDI case PBCMGH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.4 years (880 days).
Specimen 0DV5SE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3886da4-517d-4904-8901-f7705643d188.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV5RT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0432c15d-9e09-4faf-9e3f-d0792188a14c

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Intron 2, Missense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDR2 | c.1490G>T p.G497V | Missense Mutation (SNP) | VAF 110/1015 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR52N1 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 53/459 reads (12%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- SCARA5 | c.112+1G>A p.X38_splice | Splice Site (SNP) | VAF 67/319 reads (21%) | called by muse, mutect2, varscan2
- FFAR4 | c.532C>A p.R178= | Silent (SNP) | VAF 54/452 reads (12%) | catalogued as COSV101015566; called by muse, mutect2, varscan2
- KLK7 | c.339C>T p.L113= | Silent (SNP) | VAF 40/144 reads (28%) | called by muse, mutect2, varscan2
- RYR2 | c.12439A>C p.R4147= | Silent (SNP) | VAF 141/1247 reads (11%) | called by muse, mutect2, varscan2
- CLCC1 | c.-11-88_-11-87insT | Intron (INS) | VAF 10/79 reads (13%) | catalogued as rs10695133; called by muse*, mutect2
- RELB | c.992-33C>T | Intron (SNP) | VAF 6/62 reads (10%) | called by muse, varscan2
